Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70X, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70X-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Mass, adrenal gland, left, resection: Pheochromocytoma, no vascular or capsular invasion. See Note.

NOTE: Immunohistochemical studies for S100, synaptophysin and chromogranin are performed at . The neoplastic cells are strong and diffusely positive for S100, synaptophysin and chromogranin. This staining pattern is consistent with the diagnosis of pheochromocytoma.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology, . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: pheochromocytoma on left
Specimen Taken For
Protocol: 01 - Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: pheochromocytoma on left adrenal
Post-Operative
Diagnosis: pheochromocytoma Pre-Operative Diagnosis: pheochromocytoma

SPECIMENS SUBMITTED: 1. ADRENAL MASS, LEFT, Gland and mass

GROSS DESCRIPTION: Received fresh in a container labeled with the patient's name, medical record number, and "left adrenal gland mass". It is a specimen weighing 22.8 grams and measuring 6 x 6 x 2 cm overall consisting of a well-circumscribed nodule measuring 3.5 x 3 x 2 cm with associated adipose tissue measuring 6 x 1.5 x 1 cm in which there is normal-appearing adrenal gland measuring 4 x 1.5 x 0.5 cm from which the nodule arises. Gross photographs are taken. The nodule is bisected revealing a partially cystic and partially friable solid cut surface. Approximately 50% of solid tumor is procured for and 0.3 x 0.3 x 0.3 cm of solid tumor for 50% of alternating sections of the normal-appearing adrenal gland are procured also for . Also procured are 2 x 1 x 0.5 cm of adipose tissue for . The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. The procurement was performed by

In Surgical Pathology, the specimen received matches the above description. Representative sections from the tumor mass are submitted in cassettes . Representative sections of grossly normal adrenal

[page 2 of 2]
Surgical Pathology (OrderID: _____)

Final Results

gland are submitted in cassette. The remaining tissue is saved in formalin.

Gross Description dictated by _____

No consultants

Accessioned:

Final Report Signed Out: _____

<Resident Signature> _____

<Sign Out Dr. Signature> _____

Date Report Signed: _____

Case #	W 7/25/13	Yes	No
Prevalence Discrepancy			✓

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID: _____

Requested By: _____

Do not file in Medical Record

Source: NCI Genomic Data Commons file 7c337960-5d7f-469f-b9b2-a3ef64437aa4 (TCGA-QR-A70X.CE7AC7ED-E1FD-4F05-935A-39A845CBFBA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).